Somatic mutation profile of tumor specimen HCM-WCMC-0788-C34-01A (aliquot HCM-WCMC-0788-C34-01A-20D-A87L-36) from HCMI case HCM-WCMC-0788-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.6 years (26,516 days).
Specimen HCM-WCMC-0788-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a8d3f45-05de-4f57-8711-cc6ffc145363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0788-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0788-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af2e5245-d34e-44a1-b2ee-c5b9d11f4343

The open-access MAF lists 518 somatic variants for this specimen: 398 protein-altering or splice-affecting, 104 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 355, Silent 104, Nonsense Mutation 28, Splice Region 7, Intron 7, Frame Shift Del 4, 3'UTR 2, 3'Flank 2, 5'UTR 2, 5'Flank 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 78/451 reads (17%) | catalogued as rs768638173, CM000025, COSV62223641; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 61/386 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 86/736 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs766270124, COSV101434973; called by muse, varscan2
- ACTN2 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 42/583 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100857076; called by muse, mutect2
- ADAMTS2 | c.3562G>T p.E1188* | Nonsense Mutation (SNP) | VAF 95/647 reads (15%) | catalogued as rs768095088; called by muse, mutect2, varscan2
- ADAMTS3 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 30/638 reads (5%) | catalogued as COSV99710500; called by muse, mutect2
- ADGRD2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 37/453 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as rs1218965756, COSV58340273; called by muse, mutect2
- ADGRG4 | c.5389A>T p.K1797* | Nonsense Mutation (SNP) | VAF 91/282 reads (32%) | catalogued as COSV54956098; called by muse, mutect2, varscan2
- AGO2 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382352330; called by muse, mutect2
- AHNAK | c.14517G>T p.M4839I | Missense Mutation (SNP) | VAF 122/627 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV57219269; called by muse, mutect2, varscan2
- AMER1 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 116/413 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57658429; called by muse, mutect2, varscan2
- APBA2 | c.2052G>A p.M684I | Missense Mutation (SNP) | VAF 70/468 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV68790993; called by muse, mutect2, varscan2
- ARMC2 | c.2356T>C p.W786R | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933575; called by muse, mutect2, varscan2
- ASNSD1 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs769391454, COSV53622907; called by muse, mutect2
- ATRX | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64883000, COSV64887319; called by muse, mutect2, varscan2
- AWAT1 | c.258C>A p.I86= | Splice Region (SNP) | VAF 62/231 reads (27%) | catalogued as rs372598538; called by muse, mutect2, varscan2
- BNC1 | c.2561C>G p.T854S | Missense Mutation (SNP) | VAF 33/738 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100596933; called by muse, mutect2
- BRINP1 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 49/491 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.043); catalogued as COSV99776688; called by muse, mutect2
- C9orf153 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs757025356; called by muse, mutect2, varscan2
- CACNA1E | c.6708C>A p.H2236Q (on ENST00000367573 / NM_001205293.3; = p.H2193Q on NM_000721.4) | Missense Mutation (SNP) | VAF 90/678 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV62415033; called by muse, mutect2, varscan2
- CASR | c.2258G>C p.G753A (on ENST00000490131; = p.G830A on NM_000388.4) | Missense Mutation (SNP) | VAF 55/561 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56139016; called by muse, mutect2, varscan2
- CDKL2 | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 96/535 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs150511430, COSV99048749; called by muse, mutect2, varscan2
- CLEC20A | c.33C>A p.C11* | Nonsense Mutation (SNP) | VAF 88/554 reads (16%) | catalogued as rs1048187920; called by muse, mutect2, varscan2
- CLK1 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 73/448 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs749539322; called by muse, mutect2, varscan2
- CLMN | c.312G>T p.L104F | Missense Mutation (SNP) | VAF 98/581 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100112594; called by muse, mutect2, varscan2
- CNTNAP2 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs757574876, COSV62159605, COSV62222788, COSV62222789; called by muse, mutect2
- COL25A1 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889707262; called by muse, mutect2
- COL4A3 | c.3062G>T p.G1021V | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59259749; called by muse, mutect2, varscan2
- COL5A2 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411245; called by muse, mutect2, varscan2
- COMP | c.1790C>A p.A597E | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1224528574; called by muse, mutect2, varscan2
- DCHS1 | c.9707G>T p.R3236L | Missense Mutation (SNP) | VAF 54/722 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54996730; called by muse, mutect2
- DDX3X | c.682G>T p.G228* (on ENST00000399959; = p.G229* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 21/247 reads (9%) | catalogued as COSV101302547, COSV67864369; called by muse, mutect2
- DPYS | c.1090G>T p.V364L | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138282507, CM102075; called by muse, mutect2, varscan2
- DRD2 | c.1137C>A p.L379= | Splice Region (SNP) | VAF 50/289 reads (17%) | catalogued as COSV60763426; called by muse, mutect2, varscan2
- EGLN3 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs375310922; called by muse, mutect2, varscan2
- EID2B | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 44/559 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs1389173360; called by muse, mutect2
- ELAVL3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs747316633, COSV63645512; called by muse, mutect2
- EPHA5 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 67/409 reads (16%) | catalogued as COSV56655170; called by muse, mutect2, varscan2
- ERICH3 | c.3930G>T p.Q1310H | Missense Mutation (SNP) | VAF 60/984 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV100446181; called by muse, mutect2
- ETFBKMT | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371728423; called by muse, mutect2, varscan2
- EYS | c.1107C>A p.S369R | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV61000228; called by muse, mutect2
- FAM160A1 | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 50/820 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1411229778; called by muse, mutect2
- FLG2 | c.2849A>C p.Q950P | Missense Mutation (SNP) | VAF 47/734 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs1288308098, COSV101166091; called by muse, mutect2
- FOXG1 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 62/583 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57394865; called by muse, mutect2, varscan2
- FOXG1 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 59/578 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471936774; called by muse, mutect2, varscan2
- GABRB3 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 79/516 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54661471, COSV54667048; called by muse, mutect2, varscan2
- GALNT5 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 75/470 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52036370; called by muse, mutect2, varscan2
- GPRC5B | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 52/596 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as rs1411388555; called by muse, mutect2
- GRIA3 | c.1886C>A p.S629Y | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52080739; called by muse, mutect2, varscan2
- GRIPAP1 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 123/441 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1284469158, COSV64551985; called by muse, mutect2, varscan2
- HDAC5 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 22/654 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1252546644; called by muse, mutect2
- HERC2 | c.13202G>T p.R4401L | Missense Mutation (SNP) | VAF 28/737 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55309383; called by muse, mutect2
- HRNR | c.381T>G p.F127L | Missense Mutation (SNP) | VAF 84/474 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64263737; called by muse, mutect2, varscan2
- HSF5 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 58/478 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100051270, COSV60201683; called by muse, mutect2, varscan2
- HTRA4 | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100205602; called by muse, mutect2
- IFFO2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 28/696 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1443004685, COSV69086375; called by muse, mutect2
- IGHV1-2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 39/585 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs782446988; called by muse, mutect2
- IGSF9 | c.1883G>T p.R628L (on ENST00000368094 / NM_001135050.2; = p.R612L on NM_020789.4) | Missense Mutation (SNP) | VAF 33/816 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as rs928432972, COSV100829632; called by muse, mutect2
- KLK5 | c.741del p.P248Lfs*65 | Frame Shift Del (DEL) | VAF 38/338 reads (11%) | catalogued as rs759781166; called by mutect2, varscan2
- KPRP | c.602G>C p.C201S | Missense Mutation (SNP) | VAF 46/679 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100908644; called by muse, mutect2
- KRT75 | c.1643G>C p.S548T | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV52872913; called by muse, mutect2
- KTI12 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 51/469 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs750477587; called by muse, mutect2, varscan2
- L1TD1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 16/454 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.242); catalogued as COSV63134301; called by muse, mutect2
- LOXL1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 72/434 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV56096111; called by muse, varscan2
- MAGEA4 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52342551; called by muse, mutect2, varscan2
- MDGA2 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 32/531 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as rs199658941; called by muse, mutect2
- MGAM | c.5240G>T p.G1747V | Missense Mutation (SNP) | VAF 52/794 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101527382, COSV72075476; called by muse, mutect2
- MMP16 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54171969; called by muse, mutect2
- MOXD1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 59/436 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV63452444; called by muse, mutect2, varscan2
- MPEG1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 77/517 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs551823490, COSV57090064; called by muse, mutect2, varscan2
- MPPED2 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 19/479 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV63896195; called by muse, mutect2
- MROH1 | c.3571G>A p.V1191M | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs983052182; called by muse, mutect2, varscan2
- MRPL22 | c.313A>C p.K105Q | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs200195885; called by muse, mutect2, varscan2
- MS4A2 | c.360G>T p.R120S | Missense Mutation (SNP) | VAF 50/377 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV54014400; called by muse, mutect2, varscan2
- MT1H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 86/444 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV60090520; called by muse, mutect2, varscan2
- MUC5B | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs750488803; called by mutect2, varscan2
- MXRA5 | c.7999G>T p.G2667* | Nonsense Mutation (SNP) | VAF 91/369 reads (25%) | catalogued as COSV54235133; called by muse, mutect2, varscan2
- MXRA5 | c.6991G>T p.G2331W | Missense Mutation (SNP) | VAF 54/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54239645; called by muse, mutect2, varscan2
- NAT1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 29/401 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138061602; called by muse, mutect2
- NEB | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50808237; called by muse, mutect2
- NMUR2 | c.450C>G p.H150Q | Missense Mutation (SNP) | VAF 82/542 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54921052; called by muse, mutect2, varscan2
- NRXN1 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 80/941 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100457073; called by muse, mutect2
- OPLAH | c.2347G>T p.V783L | Missense Mutation (SNP) | VAF 151/568 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1554758672; called by muse, mutect2, varscan2
- OR10S1 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 83/527 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775734563, COSV73342735; called by muse, mutect2, varscan2
- OR2W3 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 83/471 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1388972305; called by muse, mutect2, varscan2
- OR4A15 | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59036503; called by muse, mutect2
- OR6K2 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs763659944; called by muse, mutect2
- PAPPA2 | c.1320C>A p.H440Q | Missense Mutation (SNP) | VAF 97/540 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs763446637; called by muse, mutect2, varscan2
- PCDH10 | c.1787C>A p.P596Q | Missense Mutation (SNP) | VAF 30/614 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52092050; called by muse, mutect2
- PCDH15 | c.2316C>A p.Y772* | Nonsense Mutation (SNP) | VAF 27/501 reads (5%) | catalogued as COSV57412543; called by muse, mutect2
- PCDHA10 | c.1688C>A p.A563E | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs1554150585, COSV100252212, COSV56491089; called by muse, mutect2, varscan2
- PIK3CG | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs765080806, COSV63245292; called by muse, mutect2
- PROX1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 22/700 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.192); catalogued as COSV54778426; called by muse, mutect2
- PRPF3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 79/531 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100254773, COSV61396165; called by muse, mutect2, varscan2
- PYHIN1 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100932334, COSV100932348; called by muse, mutect2
- RGSL1 | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 24/588 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1182688990; called by muse, mutect2
- SBNO2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446324272; called by muse, mutect2, varscan2
- SCN2A | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 52/452 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs796053187, COSV51855359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs763078635; called by muse, mutect2, varscan2
- SEMA5A | c.2027G>T p.R676L | Missense Mutation (SNP) | VAF 72/703 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66799890; called by muse, mutect2, varscan2
- SEMA5A | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 60/530 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs202102793, COSV66795676; called by muse, mutect2, varscan2
- SERPINA5 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 79/627 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as COSV61574307; called by muse, mutect2, varscan2
- SETD3 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 98/975 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV100074987; called by muse, mutect2
- SHANK1 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 101/539 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99521565; called by muse, mutect2, varscan2
- SLC28A1 | c.1754G>T p.C585F | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54487349; called by muse, varscan2
- SLC38A10 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 48/696 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.101); catalogued as rs755525430, COSV99917988; called by muse, mutect2
- SLITRK3 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 96/565 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV53847696, COSV53847840; called by muse, mutect2, varscan2
- SREBF1 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 63/742 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768240923, COSV55399928; called by muse, mutect2
- ST18 | c.2259G>C p.K753N | Missense Mutation (SNP) | VAF 124/558 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52485410; called by muse, mutect2, varscan2
- STAB2 | c.3775C>A p.H1259N | Missense Mutation (SNP) | VAF 58/624 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV104429580; called by muse, mutect2
- SVEP1 | c.9854G>T p.R3285I | Missense Mutation (SNP) | VAF 33/410 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.399); catalogued as rs370695796, COSV52837509; called by muse, mutect2
- SZT2 | c.8327C>A p.P2776H (on ENST00000634258 / NM_001365999.1; = p.P2719H on NM_015284.4) | Missense Mutation (SNP) | VAF 66/684 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100987307; called by muse, mutect2
- TACC2 | c.4841G>T p.G1614V | Missense Mutation (SNP) | VAF 45/555 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs150804431; called by muse, mutect2
- TBX3 | c.1480G>T p.A494S (on ENST00000257566 / NM_016569.4; = p.A474S on NM_005996.4) | Missense Mutation (SNP) | VAF 109/481 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57471303; called by muse, varscan2
- TLL1 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as COSV50267744; called by muse, mutect2
- TMEM200A | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 68/444 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV51653964; called by muse, mutect2, varscan2
- TNN | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 43/702 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.459); catalogued as rs200816440; called by muse, mutect2
- TNXB | c.11267C>A p.P3756H (on ENST00000647633; = p.P3509H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/502 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961333651; called by muse, mutect2
- TRPM1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 116/1359 reads (9%) | catalogued as rs756797592, COSV56630812; called by muse, mutect2
- USP43 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 17/490 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as rs1247839747; called by muse, mutect2
- VN1R4 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.317); catalogued as COSV100237584, COSV60805600; called by muse, mutect2
- XKR3 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 30/352 reads (9%) | catalogued as COSV58887921; called by muse, mutect2
- XPO7 | c.2855G>A p.R952H | Missense Mutation (SNP) | VAF 62/720 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as rs368230317; called by muse, mutect2
- ZNF496 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 98/594 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54174957, COSV54180417; called by muse, mutect2, varscan2
- ZNF691 | c.403C>T p.R135W (on ENST00000372502; = p.R104W on NM_015911.3) | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368885981, COSV65289284; called by muse, mutect2
- ZNF804A | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56469794; called by muse, mutect2, varscan2
- ZUP1 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754412333; called by muse, mutect2, varscan2
- ACOT2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 75/468 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSF3 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 21/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACTN2 | c.1767C>A p.Y589* | Nonsense Mutation (SNP) | VAF 46/683 reads (7%) | called by muse, mutect2
- ADAD2 | c.1708G>T p.G570W (on ENST00000315906 / NM_001145400.2; = p.G652W on NM_139174.4) | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS16 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 46/605 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- ADCY8 | c.2345A>G p.Y782C | Missense Mutation (SNP) | VAF 51/741 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ADD1 | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRG7 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 39/364 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ADNP | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 17/616 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); called by muse, mutect2
- AGBL1 | c.3156G>C p.Q1052H | Missense Mutation (SNP) | VAF 57/596 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2
- AHNAK | c.7635G>T p.K2545N | Missense Mutation (SNP) | VAF 107/580 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- AHNAK2 | c.11530G>T p.G3844W | Missense Mutation (SNP) | VAF 44/443 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ALPL | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 33/539 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ANO4 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 118/464 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- APC2 | c.3671C>A p.P1224H | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- AR | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 87/349 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ATP13A1 | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- AWAT1 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- B3GAT2 | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BFAR | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 18/604 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2
- BLK | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BMI1 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 13/331 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- BMP8B | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 71/984 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- BRINP2 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 89/656 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BTNL8 | c.542C>A p.T181K | Missense Mutation (SNP) | VAF 66/632 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- C14orf39 | c.1277T>A p.I426K | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.025); called by muse, mutect2
- CACNA1C | c.4871T>A p.I1624N | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CACNA1S | c.5540G>T p.G1847V | Missense Mutation (SNP) | VAF 136/627 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CACNA2D3 | c.2807C>T p.T936I | Missense Mutation (SNP) | VAF 37/400 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2
- CAD | c.6251G>A p.G2084E | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- CAGE1 | c.489A>T p.E163D (on ENST00000512086; = p.E27D on NM_205864.3) | Missense Mutation (SNP) | VAF 37/408 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by muse, mutect2
- CALHM4 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 74/616 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN13 | c.1561C>A p.L521I | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPN15 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CARS1 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 66/894 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.028); called by muse, mutect2
- CCDC168 | c.15510A>T p.L5170F | Missense Mutation (SNP) | VAF 31/507 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- CCDC80 | c.1746G>C p.K582N | Missense Mutation (SNP) | VAF 88/648 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.261); called by mutect2, varscan2
- CCNI | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.047); called by muse, mutect2
- CD247 | c.57A>T p.T19= | Splice Region (SNP) | VAF 92/644 reads (14%) | called by muse, mutect2, varscan2
- CD5L | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2
- CD70 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.521); called by muse, mutect2
- CEP162 | c.3216G>T p.Q1072H | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP290 | c.3586G>T p.E1196* | Nonsense Mutation (SNP) | VAF 82/361 reads (23%) | called by muse, mutect2, varscan2
- CFTR | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAD | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- CLRN1 | c.347C>A p.T116K (on ENST00000327047 / NM_174878.3; = p.T40K on NM_052995.2) | Missense Mutation (SNP) | VAF 58/611 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.549); called by muse, mutect2
- COL16A1 | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 38/692 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL3A1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2
- COL4A5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CPVL | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 22/467 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- CRACD | c.2978C>A p.A993E | Missense Mutation (SNP) | VAF 42/473 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.634); called by muse, mutect2
- CRELD1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 74/521 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CTNNA2 | c.663C>A p.Y221* | Nonsense Mutation (SNP) | VAF 54/750 reads (7%) | called by muse, mutect2
- CUX2 | c.2912C>A p.P971H | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- DGKI | c.2809G>T p.G937C | Missense Mutation (SNP) | VAF 32/483 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- DGKQ | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2
- DHX40 | c.2132C>G p.A711G | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.366); called by muse, mutect2
- DLC1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); called by muse, mutect2
- DNAH14 | c.6104A>G p.Y2035C (on ENST00000445597; = p.Y2688C on NM_001367479.1) | Missense Mutation (SNP) | VAF 59/442 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DNAH5 | c.8233G>A p.G2745R | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNAH9 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- DNAH9 | c.6445G>T p.V2149L | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.247); called by muse, mutect2
- DOT1L | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPH6 | c.414A>T p.L138F | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2
- DRD2 | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 83/544 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- DUSP4 | c.1102T>G p.F368V | Missense Mutation (SNP) | VAF 23/486 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); called by muse, mutect2
- DYNC2H1 | c.4681C>A p.H1561N | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- DYSF | c.1641G>T p.G547= | Splice Region (SNP) | VAF 72/423 reads (17%) | called by muse, mutect2, varscan2
- E4F1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 27/590 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); called by muse, mutect2
- EHD3 | c.1474A>G p.K492E | Missense Mutation (SNP) | VAF 84/579 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ERP44 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 42/675 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- EXOC3L1 | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.226); called by muse, mutect2
- F5 | c.6491G>T p.W2164L | Missense Mutation (SNP) | VAF 71/531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM214B | c.1307A>T p.Q436L | Missense Mutation (SNP) | VAF 70/603 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FAM83H | c.3200A>G p.N1067S | Missense Mutation (SNP) | VAF 44/701 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAT3 | c.3338C>T p.S1113L | Missense Mutation (SNP) | VAF 31/578 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); called by muse, mutect2
- FHAD1 | c.4079T>C p.L1360P | Missense Mutation (SNP) | VAF 56/502 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLNC | c.6688C>A p.R2230S | Missense Mutation (SNP) | VAF 56/586 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- FLNC | c.7744C>A p.H2582N | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2
- FOXD1 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2
- FRMPD4 | c.1678T>A p.F560I | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FZD10 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, varscan2
- GASK1B | c.780T>A p.C260* | Nonsense Mutation (SNP) | VAF 93/774 reads (12%) | called by muse, mutect2, varscan2
- GMNC | c.584T>A p.L195* | Nonsense Mutation (SNP) | VAF 68/575 reads (12%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.849); called by muse, mutect2
- GPR27 | c.1038G>T p.R346S | Missense Mutation (SNP) | VAF 60/626 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2
- GREB1 | c.3550G>T p.G1184W | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- GRIN2B | c.735C>A p.N245K | Missense Mutation (SNP) | VAF 73/626 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GSKIP | c.88A>T p.M30L | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- H6PD | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 30/601 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2
- HAS1 | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 45/655 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- HAS1 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 84/475 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HNRNPA1L2 | c.40A>T p.R14W | Missense Mutation (SNP) | VAF 27/693 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2
- HOXA11 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 157/619 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HRNR | c.1789T>A p.Y597N | Missense Mutation (SNP) | VAF 48/823 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.146); called by muse, mutect2
- HSD3B2 | c.847T>A p.W283R | Missense Mutation (SNP) | VAF 27/570 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- HYDIN | c.13605del p.F4536Lfs*16 | Frame Shift Del (DEL) | VAF 49/396 reads (12%) | called by mutect2, varscan2
- IARS2 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- IFI27 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 44/662 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- IGF2BP3 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 50/514 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2
- IGKV2D-24 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IGKV2D-30 | c.153C>A p.Y51* | Nonsense Mutation (SNP) | VAF 52/535 reads (10%) | called by muse, mutect2, varscan2
- IMPG1 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- IRS1 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 48/634 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IST1 | c.313C>G p.L105V (on ENST00000535424 / NM_001270976.1; = p.L92V on NM_014761.4) | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- KCNG1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCNH8 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNJ6 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 77/496 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIF26A | c.1845G>A p.M615I | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- KIR3DL1 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KIRREL1 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 95/583 reads (16%) | called by muse, mutect2, varscan2
- KLHL1 | c.1546G>T p.G516C | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMO | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KRTAP12-2 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 50/535 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2
- LAMA5 | c.8809G>T p.D2937Y | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LAMB2 | c.2052G>T p.E684D | Missense Mutation (SNP) | VAF 37/471 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2
- LAMP3 | c.238A>C p.T80P | Missense Mutation (SNP) | VAF 65/498 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LGI4 | c.628+8G>A | Splice Region (SNP) | VAF 84/652 reads (13%) | called by muse, varscan2
- LILRB5 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 77/720 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LIPI | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- LMX1A | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 73/489 reads (15%) | called by muse, mutect2, varscan2
- LOXL1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, varscan2
- LOXL1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 70/394 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- LOXL1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 66/497 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- LRP1B | c.10057C>A p.P3353T | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC66 | c.2064G>T p.Q688H | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); called by muse, mutect2
- LRRC66 | c.627A>T p.K209N | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2
- LRRTM1 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 56/640 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2
- MAGEB6 | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 28/415 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2
- MAP4K1 | c.1352C>A p.T451N | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MEI4 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2
- MKLN1 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 37/544 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); called by muse, mutect2
- MMP16 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 64/341 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MRC1 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 77/531 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A14 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 67/505 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSH4 | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); called by muse, mutect2
- MSL3 | c.895A>G p.T299A (on ENST00000312196 / NM_078629.4; = p.T133A on NM_006800.4) | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2
- MST1 | c.1942A>T p.I648F | Missense Mutation (SNP) | VAF 62/732 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.076); called by muse, mutect2
- MTOR | c.5461A>T p.S1821C | Missense Mutation (SNP) | VAF 34/764 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2
- MYOM3 | c.1432+1G>T p.X478_splice | Splice Site (SNP) | VAF 18/249 reads (7%) | called by muse, mutect2
- NIN | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 74/500 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKAIN2 | c.323G>T p.W108L | Missense Mutation (SNP) | VAF 62/652 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- NKX3-2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 27/400 reads (7%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- NOBOX | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOLC1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 48/638 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- NOSTRIN | c.1357C>A p.Q453K (on ENST00000317647 / NM_001039724.4; = p.Q375K on NM_052946.3) | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NPR3 | c.1182C>A p.N394K | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSUN7 | c.929T>A p.M310K | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OCA2 | c.611G>T p.W204L | Missense Mutation (SNP) | VAF 68/644 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- OGFR | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 24/505 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR10K2 | c.219C>A p.Y73* | Nonsense Mutation (SNP) | VAF 62/448 reads (14%) | called by muse, mutect2, varscan2
- OR14C36 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 49/609 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by muse, mutect2
- OR14K1 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 22/599 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- OR1C1 | c.941A>T p.Q314L | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- OR2A5 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 49/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR2H1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 77/968 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- OR52E5 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5H15 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 65/580 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR8G5 | c.915del p.R308Efs*66 (on ENST00000641992; = p.R308Efs*? on NM_001005198.1) | Frame Shift Del (DEL) | VAF 44/341 reads (13%) | called by mutect2, varscan2
- P3H1 | c.2055+3G>A | Splice Region (SNP) | VAF 47/875 reads (5%) | called by muse, mutect2
- PAK6 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- PAPPA2 | c.313A>T p.S105C | Missense Mutation (SNP) | VAF 54/783 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.221); called by muse, mutect2
- PCARE | c.2276T>A p.L759H | Missense Mutation (SNP) | VAF 86/450 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCDHA1 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 148/487 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PCDHB2 | c.1687G>T p.V563L | Missense Mutation (SNP) | VAF 63/569 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PCDHB8 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 30/818 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.379); called by muse, mutect2
- PCNX4 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 53/415 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCSK5 | c.3956T>A p.V1319E | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PGD | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 20/680 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2
- PIEZO2 | c.3706G>A p.A1236T | Missense Mutation (SNP) | VAF 53/499 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PITPNM3 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 17/411 reads (4%) | called by muse, mutect2
- PKHD1 | c.5332G>T p.A1778S | Missense Mutation (SNP) | VAF 129/718 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PKP1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 29/486 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); called by muse, mutect2
- PLEKHA7 | c.2635G>T p.V879F | Missense Mutation (SNP) | VAF 78/898 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PLEKHA7 | c.1563G>T p.W521C | Missense Mutation (SNP) | VAF 58/506 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLEKHB2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2
- POLRMT | c.2360A>T p.Q787L | Missense Mutation (SNP) | VAF 83/402 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PPDPFL | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 42/472 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- PPDPFL | c.253T>A p.*85Kext*100 | Nonstop Mutation (SNP) | VAF 27/591 reads (5%) | called by muse, mutect2
- PRPF8 | c.5794G>T p.A1932S | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRT4 | c.1625C>A p.P542Q | Missense Mutation (SNP) | VAF 71/366 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PTGS2 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 32/549 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- PTPN2 | c.966A>C p.E322D | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- PTPRN2 | c.2077G>T p.V693F | Missense Mutation (SNP) | VAF 102/534 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PVR | c.797G>T p.C266F | Missense Mutation (SNP) | VAF 107/606 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PZP | c.1873A>G p.N625D | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABL6 | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.715); called by muse, mutect2
- RAG2 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 52/437 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPH1 | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RBM22 | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 135/541 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM46 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RFTN2 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.316); called by muse, mutect2
- RFX6 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 40/374 reads (11%) | called by muse, mutect2, varscan2
- RGS22 | c.3026A>G p.E1009G | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- RPTN | c.1903G>T p.G635* | Nonsense Mutation (SNP) | VAF 36/840 reads (4%) | called by muse, mutect2
- RSPO1 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RXFP1 | c.609G>T p.L203= | Splice Region (SNP) | VAF 35/335 reads (10%) | called by muse, mutect2
- SALL4 | c.2978G>A p.G993E | Missense Mutation (SNP) | VAF 81/648 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SCAF1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- SEMA6D | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- SEMA6D | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SENP5 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SERF2 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 27/754 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- SERPINA11 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 137/588 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- SLC12A7 | c.2566G>T p.G856C | Missense Mutation (SNP) | VAF 107/474 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A6 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.089); called by muse, mutect2
- SLC28A3 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 41/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNRNP200 | c.3915G>T p.Q1305H | Missense Mutation (SNP) | VAF 82/555 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SNX25 | c.270G>T p.L90F | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORCS3 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 35/435 reads (8%) | called by muse, mutect2
- SOX9 | c.1034C>A p.P345H | Missense Mutation (SNP) | VAF 19/350 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.147); called by muse, mutect2
- SPECC1 | c.2458G>T p.V820F | Missense Mutation (SNP) | VAF 20/680 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPEM1 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SUN1 | c.1453A>C p.K485Q (on ENST00000405266 / NM_001367651.1; = p.K365Q on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/389 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SV2C | c.847T>C p.C283R | Missense Mutation (SNP) | VAF 76/639 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SVEP1 | c.8966G>T p.C2989F | Missense Mutation (SNP) | VAF 43/570 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNE3 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 43/417 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SYNPR | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2
- TACR3 | c.958A>T p.I320F | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TAF1L | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 123/711 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TBX22 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 119/395 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX3 | c.1370C>A p.P457Q (on ENST00000257566 / NM_016569.4; = p.P437Q on NM_005996.4) | Missense Mutation (SNP) | VAF 93/542 reads (17%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); called by muse, varscan2
- TCERG1L | c.1239T>A p.D413E | Missense Mutation (SNP) | VAF 33/509 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2
- TEC | c.858dup p.T287Yfs*12 | Frame Shift Ins (INS) | VAF 70/370 reads (19%) | called by mutect2, varscan2
- TENM2 | c.3104C>A p.P1035Q (on ENST00000518659 / NM_001122679.2; = p.P803Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 98/634 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TFAP2D | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TFIP11 | c.1433A>T p.H478L | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TGS1 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMMDC1 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 90/611 reads (15%) | called by muse, mutect2, varscan2
- TMC1 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 30/552 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.536); called by muse, mutect2
- TMC3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 52/650 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- TNR | c.989A>T p.E330V | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.096); called by muse, mutect2
- TNR | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 28/662 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.374); called by muse, mutect2
- TP53RK | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 38/608 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2
- TPM1 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TRANK1 | c.5929T>C p.Y1977H | Missense Mutation (SNP) | VAF 68/734 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- TRIM51 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2
- TRPM7 | c.1895T>C p.M632T | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM8 | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 32/457 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2
- TSHZ3 | c.2756A>T p.E919V | Missense Mutation (SNP) | VAF 54/684 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.27); called by muse, mutect2
- TTC39A | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 36/621 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTLL6 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 50/561 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TULP4 | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- TUSC3 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- U2SURP | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
- UBE2L5 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 38/640 reads (6%) | called by muse, mutect2
- UNC45B | c.1631T>A p.V544E | Missense Mutation (SNP) | VAF 51/505 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5D | c.2332G>T p.V778L | Missense Mutation (SNP) | VAF 35/544 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2
- UNCX | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2
- VCX2 | c.191C>A p.A64E | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- WDR59 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 118/625 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- WNT5B | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 54/474 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIAP | c.1466C>G p.T489S | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZC4H2 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 62/381 reads (16%) | called by muse, mutect2, varscan2
- ZC4H2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 132/484 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZIC4 | c.689G>C p.G230A | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 56/444 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZNF143 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 48/584 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF208 | c.2975A>T p.K992M | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF292 | c.7621C>G p.Q2541E | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2
- ZNF431 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- ZNF461 | c.1584del p.K529Rfs*33 | Frame Shift Del (DEL) | VAF 35/317 reads (11%) | called by mutect2, varscan2
- ZNF480 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- ZNF569 | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF721 | c.790C>A p.P264T (on ENST00000338977; = p.P276T on NM_133474.4) | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- ZNF799 | c.1736A>T p.E579V | Missense Mutation (SNP) | VAF 60/447 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF804A | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ZNF81 | c.1457A>T p.Q486L | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF831 | c.2836C>G p.P946A | Missense Mutation (SNP) | VAF 118/627 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ZNF84 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABHD13 | c.492A>T p.G164= | Silent (SNP) | VAF 40/360 reads (11%) | called by muse, mutect2, varscan2
- ACOT2 | c.867G>T p.G289= | Silent (SNP) | VAF 75/474 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.351A>G p.E117= | Silent (SNP) | VAF 55/386 reads (14%) | called by muse, mutect2, varscan2
- ALK | c.3477G>A p.Q1159= | Silent (SNP) | VAF 32/620 reads (5%) | called by muse, mutect2
- AMOTL1 | c.2499G>T p.L833= | Silent (SNP) | VAF 66/512 reads (13%) | called by muse, mutect2, varscan2
- ANK2 | c.3459G>T p.V1153= | Silent (SNP) | VAF 25/773 reads (3%) | called by muse, mutect2
- APOL5 | c.267C>A p.S89= | Silent (SNP) | VAF 116/588 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.1794G>T p.S598= | Silent (SNP) | VAF 38/449 reads (8%) | catalogued as rs778000637; called by muse, mutect2
- CCDC173 | c.1515T>C p.R505= | Silent (SNP) | VAF 32/504 reads (6%) | called by muse, mutect2
- CDH22 | c.684G>T p.T228= | Silent (SNP) | VAF 97/430 reads (23%) | catalogued as COSV64837665; called by muse, mutect2, varscan2
- CMA1 | c.66C>A p.I22= | Silent (SNP) | VAF 43/391 reads (11%) | catalogued as rs183530742; called by muse, mutect2, varscan2
- CNTNAP2 | c.1608G>T p.V536= | Silent (SNP) | VAF 30/456 reads (7%) | called by muse, mutect2
- COL15A1 | c.528C>A p.L176= | Silent (SNP) | VAF 48/622 reads (8%) | catalogued as COSV66647096; called by muse, mutect2
- COQ8B | c.180C>T p.R60= | Silent (SNP) | VAF 76/635 reads (12%) | called by muse, mutect2, varscan2
- CSMD3 | c.7584C>A p.L2528= (on ENST00000297405 / NM_001363185.1; = p.L2424= on NM_052900.3) | Silent (SNP) | VAF 25/457 reads (5%) | called by muse, mutect2
- DENND5B | c.834G>T p.L278= | Silent (SNP) | VAF 54/412 reads (13%) | called by muse, mutect2
- DPP6 | c.2034G>T p.R678= (on ENST00000377770 / NM_001364500.2; = p.R616= on NM_001936.5) | Silent (SNP) | VAF 135/646 reads (21%) | called by muse, mutect2, varscan2
- EIF4EBP2 | c.132C>T p.S44= | Silent (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- EME1 | c.138G>A p.V46= | Silent (SNP) | VAF 24/486 reads (5%) | catalogued as COSV99869184; called by muse, mutect2
- EYA1 | c.1056A>T p.P352= | Silent (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
- FAM47C | c.528G>C p.T176= | Silent (SNP) | VAF 79/287 reads (28%) | catalogued as COSV63727816; called by muse, mutect2, varscan2
- FBXO8 | c.24G>T p.V8= | Silent (SNP) | VAF 26/474 reads (5%) | called by muse, mutect2
- FGGY | c.1395G>T p.V465= | Silent (SNP) | VAF 13/360 reads (4%) | called by muse, mutect2
- FPGS | c.1050C>T p.H350= | Silent (SNP) | VAF 30/498 reads (6%) | called by muse, mutect2
- FZD10 | c.252C>G p.R84= | Silent (SNP) | VAF 72/398 reads (18%) | called by muse, varscan2
- GABRA6 | c.219G>A p.V73= | Silent (SNP) | VAF 38/375 reads (10%) | called by muse, mutect2, varscan2
- GIMAP7 | c.156G>T p.R52= | Silent (SNP) | VAF 105/666 reads (16%) | called by muse, mutect2, varscan2
- GLIS3 | c.1068C>T p.Y356= | Silent (SNP) | VAF 64/539 reads (12%) | catalogued as rs371355667; called by muse, mutect2, varscan2
- GREB1 | c.3549G>A p.Q1183= | Silent (SNP) | VAF 30/560 reads (5%) | catalogued as rs763729538; called by muse, mutect2
- GRIN3B | c.1366C>T p.L456= | Silent (SNP) | VAF 30/420 reads (7%) | catalogued as rs371910067, COSV52263961; called by muse, mutect2
- HEPH | c.42T>A p.V14= | Silent (SNP) | VAF 43/352 reads (12%) | called by muse, mutect2, varscan2
- HIVEP1 | c.444C>T p.S148= | Silent (SNP) | VAF 88/633 reads (14%) | catalogued as rs763642376; called by muse, mutect2, varscan2
- KCNH4 | c.852C>G p.T284= | Silent (SNP) | VAF 50/411 reads (12%) | catalogued as COSV52916589; called by muse, mutect2, varscan2
- KCNN3 | c.807G>A p.K269= | Silent (SNP) | VAF 24/650 reads (4%) | called by muse, mutect2
- KIF1A | c.558C>A p.V186= | Silent (SNP) | VAF 73/433 reads (17%) | called by muse, mutect2, varscan2
- KMT5C | c.177G>C p.R59= | Silent (SNP) | VAF 79/643 reads (12%) | catalogued as rs1348617615; called by muse, mutect2, varscan2
- KRTAP27-1 | c.141G>A p.L47= | Silent (SNP) | VAF 66/548 reads (12%) | catalogued as rs1292212429; called by muse, mutect2, varscan2
- LDLRAD2 | c.447C>A p.R149= | Silent (SNP) | VAF 24/558 reads (4%) | called by muse, mutect2
- LMTK2 | c.3819G>A p.G1273= | Silent (SNP) | VAF 47/664 reads (7%) | catalogued as rs760036519; called by muse, mutect2
- LOXL1 | c.504C>T p.R168= | Silent (SNP) | VAF 76/465 reads (16%) | called by muse, varscan2
- LOXL1 | c.879C>T p.P293= | Silent (SNP) | VAF 78/518 reads (15%) | called by muse, mutect2
- LRRN2 | c.390C>A p.T130= | Silent (SNP) | VAF 75/478 reads (16%) | called by muse, mutect2, varscan2
- LRTM2 | c.996C>A p.G332= | Silent (SNP) | VAF 60/479 reads (13%) | called by muse, mutect2, varscan2
- MAGEB3 | c.933G>A p.L311= | Silent (SNP) | VAF 45/331 reads (14%) | catalogued as COSV64397235; called by muse, mutect2, varscan2
- MED13L | c.6006A>G p.S2002= | Silent (SNP) | VAF 157/580 reads (27%) | called by muse, mutect2, varscan2
- MIB2 | c.2835T>A p.A945= | Silent (SNP) | VAF 20/540 reads (4%) | called by muse, mutect2
- MKLN1 | c.27G>T p.A9= | Silent (SNP) | VAF 36/542 reads (7%) | called by muse, mutect2
- MPC1L | c.306C>T p.L102= | Silent (SNP) | VAF 40/321 reads (12%) | called by muse, mutect2, varscan2
- MTOR | c.5229G>T p.L1743= | Silent (SNP) | VAF 40/395 reads (10%) | called by muse, mutect2, varscan2
- MYH2 | c.4314G>A p.V1438= | Silent (SNP) | VAF 70/432 reads (16%) | called by muse, mutect2, varscan2
- MYO18B | c.5985G>T p.R1995= | Silent (SNP) | VAF 30/286 reads (10%) | called by muse, mutect2, varscan2
- NKX2-2 | c.175C>T p.L59= | Silent (SNP) | VAF 75/621 reads (12%) | called by muse, mutect2, varscan2
- NOBOX | c.183C>T p.S61= | Silent (SNP) | VAF 60/498 reads (12%) | catalogued as rs762791118; called by muse, mutect2, varscan2
- NRAP | c.3873C>A p.L1291= (on ENST00000359988 / NM_001322945.2; = p.L1256= on NM_006175.4) | Silent (SNP) | VAF 32/438 reads (7%) | called by muse, mutect2
- NTRK3 | c.279G>T p.T93= | Silent (SNP) | VAF 58/669 reads (9%) | catalogued as COSV58121730; called by muse, mutect2
- OR10J3 | c.642G>T p.L214= | Silent (SNP) | VAF 46/523 reads (9%) | catalogued as COSV59955656; called by muse, mutect2
- OR10J5 | c.324C>A p.A108= | Silent (SNP) | VAF 44/450 reads (10%) | called by muse, mutect2
- OR2T2 | c.285C>T p.F95= | Silent (SNP) | VAF 50/1984 reads (3%) | catalogued as rs1237183660, COSV61618100; called by muse, mutect2
- OR52L1 | c.795C>T p.V265= | Silent (SNP) | VAF 50/493 reads (10%) | called by muse, mutect2, varscan2
- OR56A5 | c.519A>T p.A173= | Silent (SNP) | VAF 42/481 reads (9%) | called by muse, mutect2
- OR5B17 | c.939C>A p.V313= | Silent (SNP) | VAF 52/252 reads (21%) | catalogued as rs942161606, COSV100641927; called by muse, mutect2
- PCARE | c.2619C>T p.T873= | Silent (SNP) | VAF 91/463 reads (20%) | called by muse, mutect2, varscan2
- PCDHB8 | c.2052C>T p.A684= | Silent (SNP) | VAF 114/646 reads (18%) | catalogued as rs373119743, COSV50831214; called by muse, mutect2, varscan2
- POSTN | c.2109C>G p.V703= | Silent (SNP) | VAF 17/414 reads (4%) | called by muse, mutect2
- PRDM2 | c.5061A>T p.R1687= | Silent (SNP) | VAF 54/470 reads (11%) | called by muse, mutect2, varscan2
- PREX1 | c.2704A>C p.R902= | Silent (SNP) | VAF 34/710 reads (5%) | called by muse, mutect2
- PRR23C | c.78C>T p.A26= | Silent (SNP) | VAF 40/422 reads (9%) | called by muse, mutect2
- PRRC2B | c.5733T>A p.S1911= | Silent (SNP) | VAF 42/464 reads (9%) | called by muse, mutect2
- PSG1 | c.474C>A p.P158= | Silent (SNP) | VAF 30/440 reads (7%) | called by muse, mutect2
- PTBP2 | c.1326C>G p.S442= (on ENST00000426398 / NM_001300986.2; = p.S434= on NM_021190.4) | Silent (SNP) | VAF 56/386 reads (15%) | called by muse, mutect2, varscan2
- RASA2 | c.2073A>T p.V691= | Silent (SNP) | VAF 42/540 reads (8%) | called by muse, mutect2
- RFPL4AL1 | c.189C>G p.P63= | Silent (SNP) | VAF 28/415 reads (7%) | called by muse, mutect2, varscan2
- RPH3A | c.837C>G p.A279= (on ENST00000389385 / NM_001143854.2; = p.A275= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/495 reads (12%) | called by muse, varscan2
- SAV1 | c.85C>T p.L29= | Silent (SNP) | VAF 33/435 reads (8%) | called by muse, mutect2
- SCART1 | c.861G>A p.S287= | Silent (SNP) | VAF 42/564 reads (7%) | catalogued as rs764816021; called by muse, mutect2
- SEMA4F | c.642G>T p.R214= | Silent (SNP) | VAF 44/431 reads (10%) | catalogued as rs146486166; called by muse, mutect2, varscan2
- SEPTIN3 | c.261C>T p.I87= | Silent (SNP) | VAF 30/476 reads (6%) | catalogued as rs995227275; called by muse, mutect2
- SIGLEC5 | c.360G>C p.V120= | Silent (SNP) | VAF 50/580 reads (9%) | called by muse, varscan2
- SLC25A37 | c.756G>T p.T252= | Silent (SNP) | VAF 63/576 reads (11%) | catalogued as COSV99264216; called by muse, mutect2, varscan2
- SLC3A1 | c.306G>T p.A102= | Silent (SNP) | VAF 43/688 reads (6%) | called by muse, mutect2
- SMC4 | c.3618T>G p.A1206= | Silent (SNP) | VAF 58/664 reads (9%) | called by muse, mutect2
- SNTB2 | c.162C>T p.A54= | Silent (SNP) | VAF 71/253 reads (28%) | catalogued as rs1258437153; called by muse, mutect2, varscan2
- SPG7 | c.1005A>G p.P335= (on ENST00000268704; = p.P342= on NM_003119.4) | Silent (SNP) | VAF 85/446 reads (19%) | catalogued as rs751449066; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAFA4 | c.264G>T p.R88= | Silent (SNP) | VAF 48/539 reads (9%) | called by muse, mutect2
- TAS2R16 | c.402G>A p.L134= | Silent (SNP) | VAF 55/435 reads (13%) | called by muse, mutect2, varscan2
- TBX22 | c.630C>A p.G210= | Silent (SNP) | VAF 69/291 reads (24%) | called by muse, mutect2, varscan2
- TIMELESS | c.339G>A p.V113= | Silent (SNP) | VAF 66/449 reads (15%) | called by muse, mutect2, varscan2
- TMEM104 | c.540C>T p.G180= | Silent (SNP) | VAF 23/500 reads (5%) | called by muse, mutect2
- TMEM221 | c.135C>G p.R45= | Silent (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2
- TMEM63B | c.1965G>A p.K655= | Silent (SNP) | VAF 32/440 reads (7%) | called by muse, mutect2
- TOR4A | c.354C>T p.R118= | Silent (SNP) | VAF 33/379 reads (9%) | called by muse, mutect2
- TRANK1 | c.6606A>G p.L2202= | Silent (SNP) | VAF 42/436 reads (10%) | called by muse, mutect2
- TRAV10 | c.30G>T p.V10= | Silent (SNP) | VAF 41/575 reads (7%) | called by muse, mutect2
- TRAV23DV6 | c.171G>A p.A57= | Silent (SNP) | VAF 46/450 reads (10%) | catalogued as rs1259538831; called by muse, mutect2, varscan2
- TRIM64 | c.1053C>T p.N351= | Silent (SNP) | VAF 92/355 reads (26%) | called by muse, mutect2, varscan2
- TRPC5 | c.1443C>G p.L481= | Silent (SNP) | VAF 38/414 reads (9%) | catalogued as rs771289425; called by muse, mutect2
- UBN1 | c.750G>A p.K250= | Silent (SNP) | VAF 24/750 reads (3%) | called by muse, mutect2
- UBQLN3 | c.1113G>A p.Q371= | Silent (SNP) | VAF 65/711 reads (9%) | called by muse, mutect2
- VEGFC | c.438C>A p.V146= | Silent (SNP) | VAF 53/608 reads (9%) | catalogued as rs563624007, COSV54599762; called by muse, mutect2
- ZFHX4 | c.5064A>G p.P1688= | Silent (SNP) | VAF 42/703 reads (6%) | called by muse, mutect2
- ZNF107 | c.1041G>A p.K347= | Silent (SNP) | VAF 36/366 reads (10%) | called by muse, mutect2
- ZNF217 | c.1221G>T p.S407= | Silent (SNP) | VAF 87/843 reads (10%) | catalogued as COSV56600148; called by muse, mutect2, varscan2
- ZNF385A | c.603C>G p.L201= (on ENST00000338010 / NM_001130967.3; = p.L181= on NM_015481.3) | Silent (SNP) | VAF 74/508 reads (15%) | catalogued as COSV100567046; called by muse, mutect2, varscan2
- ZNF628 | c.963G>T p.A321= | Silent (SNP) | VAF 24/423 reads (6%) | called by muse, mutect2
- AL353804.4 | chrX:73823186 C>A | 5'Flank (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851409 C>A | 3'Flank (SNP) | VAF 71/227 reads (31%) | called by muse, mutect2, varscan2
- ATAD3B | c.*367G>T | 3'UTR (SNP) | VAF 34/424 reads (8%) | called by muse, mutect2, varscan2
- CUL7 | c.-210A>G | 5'UTR (SNP) | VAF 51/438 reads (12%) | catalogued as rs996678944; called by muse, mutect2, varscan2
- DOCK8 | c.53+45G>C | Intron (SNP) | VAF 58/498 reads (12%) | catalogued as rs758218649, COSV101213681; called by muse, mutect2
- DST | c.4296+3890G>A | Intron (SNP) | VAF 89/644 reads (14%) | catalogued as rs1174136904; called by muse, mutect2, varscan2
- KCNIP4 | c.62-101180A>T | Intron (SNP) | VAF 48/688 reads (7%) | called by muse, mutect2
- LRRFIP1 | c.154-1738A>G | Intron (SNP) | VAF 50/754 reads (7%) | catalogued as COSV55251871; called by muse, mutect2
- NPAP1L | n.156A>T | RNA (SNP) | VAF 15/382 reads (4%) | catalogued as rs965600602; called by muse, mutect2
- NR2F2 | c.-1073A>G | 5'UTR (SNP) | VAF 32/318 reads (10%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+3513A>G | Intron (SNP) | VAF 60/640 reads (9%) | called by muse, mutect2
- REG3A | c.*121C>A | 3'UTR (SNP) | VAF 36/822 reads (4%) | called by muse, mutect2
- SLAMF8 | chr1:159837953 C>A | 3'Flank (SNP) | VAF 58/821 reads (7%) | called by muse, mutect2
- TULP4 | chr6:158312100 G>T | 5'Flank (SNP) | VAF 44/406 reads (11%) | called by mutect2, varscan2
- ZNF619 | c.80+248G>T | Intron (SNP) | VAF 49/563 reads (9%) | called by muse, mutect2
- ZNF836 | c.142+27A>G | Intron (SNP) | VAF 49/457 reads (11%) | called by muse, mutect2, varscan2
